TCGA case TCGA-E1-5311 — Brain Lower Grade Glioma (TCGA-LGG)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Gliomas; Primary site: Brain; Tissue source site: Duke. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/0061e9ef-df6a-414e-af64-c88f8192e2d3

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 31 years; Vital status: Dead; Days to death: 4,084 days (11.2 years).

Diagnoses (2)
1. Oligodendroglioma, anaplastic (the primary disease): ICD-O-3 morphology code: 9451/3; ICD-10 code: C71.9; Tissue or organ of origin: Brain, NOS; Site of resection or biopsy: Nervous system, NOS; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 31.0 years (11,332 days); Year of diagnosis: 1994; Tumor grade: G3; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; First symptom longest duration: >=181 Days; First symptom prior to diagnosis: Headaches; Sites of involvement: Brain, Temporal lobe.
   Pathology details: Consistent pathology review: Yes.
   Treatment given: Treatment type: Brachytherapy, NOS; Therapeutic agents: Iodine I 131 Monoclonal Antibody 81C6; Treatment intent type: Adjuvant; Days to treatment start: 20 days; Days to treatment end: 20 days; Number of cycles: 1; Treatment dose: 40 mCi; Prescribed dose: 40; Prescribed dose units: mCi; Route of administration: Intratumoral.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Temozolomide; Initial disease status: Progressive Disease; Days to treatment start: 2,615 days (7.2 years); Days to treatment end: 2,799 days (7.7 years); Number of cycles: 6; Treatment dose: 13,200 mg; Prescribed dose: 200; Prescribed dose units: mg/m2; Route of administration: Oral.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cositecan; Initial disease status: Progressive Disease; Days to treatment start: 2,825 days (7.7 years); Days to treatment end: 2,848 days (7.8 years); Number of cycles: 1; Treatment dose: 11 mg; Prescribed dose: 2.2; Prescribed dose units: mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Radiation, External Beam; Initial disease status: Progressive Disease; Days to treatment start: 2,871 days (7.9 years); Days to treatment end: 2,919 days (8.0 years); Treatment dose: 6,000 cGy; Course number: 4; Number of fractions: 30; Treatment anatomic sites: Primary Tumor Field.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Lomustine; Initial disease status: Progressive Disease; Days to treatment start: 2,925 days (8.0 years); Days to treatment end: 3,282 days (9.0 years); Number of cycles: 8; Treatment dose: 2,000 mg; Prescribed dose: 110; Prescribed dose units: mg/m2; Route of administration: Oral.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Therapeutic agents: Celecoxib; Initial disease status: Progressive Disease; Days to treatment start: 3,282 days (9.0 years); Days to treatment end: 3,868 days (10.6 years); Number of cycles: 19; Treatment dose: 425,600 mg; Prescribed dose: 400; Prescribed dose units: mg; Route of administration: Oral.
   Treatment given: Treatment type: Hormone Therapy; Therapeutic agents: Tamoxifen; Initial disease status: Progressive Disease; Days to treatment start: 3,282 days (9.0 years); Days to treatment end: 3,749 days (10.3 years); Number of cycles: 15; Treatment dose: 84,000 mg; Prescribed dose: 100; Prescribed dose units: mg; Route of administration: Oral.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Laromustine; Initial disease status: Progressive Disease; Days to treatment start: 3,868 days (10.6 years); Days to treatment end: 3,996 days (10.9 years); Number of cycles: 3; Treatment dose: 2,040 mg; Prescribed dose: 300; Prescribed dose units: mg/m2; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Etoposide; Initial disease status: Progressive Disease; Days to treatment start: 3,996 days (10.9 years); Days to treatment end: 4,084 days (11.2 years); Number of cycles: 3; Treatment dose: 6,930 mg; Prescribed dose: 50; Prescribed dose units: mg/m2; Route of administration: Oral.
   Treatment given: Treatment type: Antiseizure Treatment; Timepoint category: Preoperative.
   Treatment given: Treatment type: Steroid Therapy; Timepoint category: Preoperative.
   Recorded as not given: Radiation Therapy, NOS to Head, Face or Neck, NOS, prior to diagnosis.
2. Recurrence of diagnosis 1 (Oligodendroglioma, anaplastic). Age at diagnosis: 38.1 years (13,934 days); Days to diagnosis: 2,602 days (7.1 years); Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Days to treatment start: 2,602 days (7.1 years); Treatment anatomic sites: Locoregional Site.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS.
   Treatment given: Treatment type: Radiation Therapy, NOS.
   Recorded as not given: Surgery, NOS to Distant Site.

Follow-up (3 entries)
- Day -8 (prior to adjuvant therapy): Karnofsky performance status: 100.
- Day 2,602 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Days to recurrence: 2,602 days (7.1 years).
- Days to follow up: 4,084 days (11.2 years); Disease response: With Tumor.

Other clinical attributes
- Timepoint category: Prior to Diagnosis; Risk factors: Headache.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-E1-5311-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Longest dimension: 1.1; Intermediate dimension: 0.6; Shortest dimension: 0.2.
  Slide TCGA-E1-5311-01A-01-TS1: Section location: Top; Percent tumor cells: 100; Percent tumor nuclei: 75; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0.
  Slide TCGA-E1-5311-01A-01-BS1: Section location: Bottom; Percent tumor cells: 95; Percent tumor nuclei: 70; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 5.
- Sample TCGA-E1-5311-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Submitted tumor site: Central nervous system; Histologic diagnosis: Oligodendroglioma; History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; History ionizing radiation to head: No; Tumor status: With tumor; Performance status timing: Pre-Adjuvant Therapy; Tumor site: Supratentorial, Temporal Lobe; Supratentorial localization: Not listed in Medical Record; History seizures: No; History headaches: Yes; Symp changes mental status: No; Symp changes visual: No; Symp changes sensory: No; Symp changes motor movement: No; First symptom longest duration: > 181 Days; History asthma: No; History eczema: No; Histor hay fever: No; History dust mold allergy: No; Allergy food diagnosis indicator: No; Allergy animals insects diagnosis indicator: No; History neoadjuvant steroid treatment: Yes; History neoadjuvant medication: Yes; Family history brain tumor: No.
- Drug treatment 1: Regimen number: 2; Therapy regimen: Progression.
- Drug treatment 1, Route of administrations: Route of administration: PO.
- Drug treatment 2: Regimen number: 6; Pharmaceutical therapy drug name: Celebrex; Therapy regimen: Progression.
- Drug treatment 3: Regimen number: 1; Pharmaceutical therapy drug name: MAGI131-81c6.
- Drug treatment 3, Route of administrations: Route of administration: Intum.
- Drug treatment 4: Regimen number: 5; Pharmaceutical therapy drug name: Ccnu; Therapy regimen: Progression.
- Drug treatment 5: Regimen number: 8; Pharmaceutical therapy drug name: VP-16; Therapy regimen: Progression.
- Drug treatment 6: Regimen number: 3; Pharmaceutical therapy drug name: Karerltecin; Therapy regimen: Progression.
- Drug treatment 6, Route of administrations: Route of administration: IV.
- Drug treatment 7: Regimen number: 7; Pharmaceutical therapy drug name: Cloretazine; Therapy regimen: Progression.
- Follow-up form: Treatment outcome first course: Stable Disease; New tumor event surgery: Yes; Tumor status: With tumor; New tumor event pharmaceutical treatment: Yes; New tumor event radiation treatment: Yes; Performance status timing: Pre-Adjuvant Therapy; New tumor event surgery met: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 4,084 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 4,084 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 2,602 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-E1-5311-01A-01D-1466-01): tumor purity 0.84, ploidy 1.92, whole-genome doublings 0.
